Somatic mutation profile of tumor specimen ALCH-B2T7-TTP1-A (aliquot ALCH-B2T7-TTP1-A-6-0-D-A780-36) from ALCHEMIST case ALCH-B2T7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 62.1 years (22,700 days).
Specimen ALCH-B2T7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ac63328-73fa-41a2-be17-c5a6abeab85f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2T7-NB1-A (Blood Derived Normal), aliquot ALCH-B2T7-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1edc861c-09ac-4185-a456-c2c318f94f40

The open-access MAF lists 87 somatic variants for this specimen: 61 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 14, Intron 7, RNA 4, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Splice Region 2, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TYMP | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224252; ClinVar: likely pathogenic; called by muse, mutect2
- ADH1C | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1170791379, COSV101565192; called by muse, mutect2
- CAMK2A | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62246639; called by muse, mutect2
- DLG5 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767375720, COSV100967587, COSV100967592; called by muse, mutect2
- EPHA3 | c.1819C>A p.Q607K | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV60722470, COSV60728109; called by muse, mutect2
- MMP16 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54190985; called by muse, mutect2
- PCDHA12 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.089); catalogued as COSV56544132; called by muse, mutect2
- PCDHB10 | c.2198C>A p.P733H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1554284487; called by muse, mutect2
- PKHD1 | c.3161C>A p.S1054Y | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61869807; called by muse, mutect2
- PRKAR1B | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs866622752; called by muse, mutect2
- RUNX1T1 | c.1797A>G p.I599M (on ENST00000265814 / NM_001198628.1; = p.I572M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs1229089945; called by muse, mutect2
- RYR2 | c.2086G>T p.G696C | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63714889; called by muse, mutect2
- SYNE2 | c.20064T>A p.H6688Q | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1355561928; called by muse, mutect2
- ADCY2 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2
- ALPP | c.71T>A p.I24N | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); called by muse, mutect2
- ATM | c.587A>T p.K196I | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2
- ATP6V1B1 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2
- BHMT | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BPIFB1 | c.1289T>C p.I430T | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- C4orf50 | c.301A>T p.R101* (on ENST00000324058; = p.R1333* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- CASP4 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- COL11A1 | c.4303-2A>G p.X1435_splice | Splice Site (SNP) | VAF 12/213 reads (6%) | called by muse, mutect2
- COLEC10 | c.485T>A p.I162N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- CTNNA3 | c.2266-2A>G p.X756_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- ELMOD1 | c.296del p.G99Efs*41 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- ENOX1 | c.1057T>C p.F353L | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2
- FAM217A | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 11/357 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- GIGYF2 | c.3216A>C p.K1072N | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.321); called by muse, mutect2
- GLI1 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- GRM3 | c.2268C>A p.F756L | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- IFT57 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 10/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV3-16 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- IGKV2D-30 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- IGKV2D-30 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 22/538 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- IGLV11-55 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITGAM | c.2793C>G p.T931= (on ENST00000648685 / NM_001145808.2; = p.T930= on NM_000632.4) | Splice Region (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- ITPRID1 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2
- KCNA5 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); called by muse, mutect2
- KEL | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- KIF15 | c.3496G>T p.G1166* | Nonsense Mutation (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- LPA | c.4280A>C p.Y1427S | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2
- MALRD1 | c.4010G>T p.G1337V | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- MAMLD1 | c.2001G>T p.R667S | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- MAST1 | c.3653C>A p.P1218Q | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYCN | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- NOD2 | c.2135C>A p.A712D | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.344); called by muse, mutect2
- PCDHB1 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2
- PCDHGC4 | c.1315A>T p.R439* | Nonsense Mutation (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- PKP2 | c.1679del p.G560Dfs*3 | Frame Shift Del (DEL) | VAF 5/93 reads (5%) | called by mutect2, pindel*
- PLCL1 | c.503T>A p.L168Q | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.07); called by muse, mutect2
- RAB3GAP1 | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- RTL1 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2
- SPATA31D3 | c.2595C>G p.H865Q | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- TEX2 | c.2644G>T p.A882S (on ENST00000583097 / NM_001288733.2; = p.A889S on NM_018469.5) | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2
- TMX3 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); called by muse, mutect2
- TRIP12 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- TRIP4 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- WAPL | c.3385C>T p.L1129F | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZNF254 | c.158-4A>G | Splice Region (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- ZNF444 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, mutect2
- ZSWIM3 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGPAT4 | c.36G>C p.L12= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- AMBP | c.648G>A p.G216= | Silent (SNP) | VAF 14/377 reads (4%) | catalogued as COSV99469202; called by muse, mutect2
- BRAF | c.1647A>T p.R549= (on ENST00000288602 / NM_001374244.1; = p.R509= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1276829336; called by muse, mutect2
- CPXM1 | c.585C>T p.V195= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- DDOST | c.150G>T p.L50= (on ENST00000415136; = p.L33= on NM_005216.5) | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- GRM6 | c.360C>A p.R120= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2
- LSAMP | c.441C>T p.S147= | Silent (SNP) | VAF 20/357 reads (6%) | catalogued as rs1559922748; called by muse, mutect2
- PCDHA10 | c.1533G>C p.A511= | Silent (SNP) | VAF 12/274 reads (4%) | catalogued as rs781800563; called by muse, mutect2
- UBTFL1 | c.231C>T p.V77= | Silent (SNP) | VAF 20/215 reads (9%) | called by muse, mutect2
- VSIG10L | c.753C>T p.H251= | Silent (SNP) | VAF 9/166 reads (5%) | catalogued as COSV58535834; called by muse, mutect2
- ZFHX3 | c.1389G>A p.A463= | Silent (SNP) | VAF 28/402 reads (7%) | catalogued as rs376777497; called by muse, mutect2
- ZFHX4 | c.5151C>A p.A1717= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as COSV50770132; called by muse, mutect2
- ZNF737 | c.96G>T p.V32= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- ZNF862 | c.669A>T p.P223= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- AC092118.1 | n.775G>C | RNA (SNP) | VAF 12/294 reads (4%) | catalogued as rs1555628839; called by muse, mutect2
- AC092675.1 | n.570C>A | RNA (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs73150876; called by muse, mutect2
- LPAL2 | n.232A>T | RNA (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- MC2R | c.*38C>T | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- MIR518B | n.22G>T | RNA (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- PHLDB1 | c.3417-40C>T | Intron (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- PTPN18 | c.414+2592A>G | Intron (SNP) | VAF 5/86 reads (6%) | catalogued as rs1254023457, COSV51558883; called by muse, mutect2
- PTPN18 | c.414+2593A>G | Intron (SNP) | VAF 5/84 reads (6%) | catalogued as rs1419922064, COSV51558941; called by muse, mutect2
- SERPINB13 | c.473-280C>A | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- SLC25A48 | c.813+549G>C | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- SMARCC1 | c.1457+38G>T | Intron (SNP) | VAF 8/180 reads (4%) | catalogued as rs1375373407; called by muse, mutect2
